Somatic mutation profile of tumor specimen TCGA-60-2706-01A (aliquot TCGA-60-2706-01A-01W-0877-08) from TCGA case TCGA-60-2706, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.8 years (21,477 days).
Specimen TCGA-60-2706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33c1e608-1841-4e4e-9c0e-3f75946b9ce6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2706-11A (Solid Tissue Normal), aliquot TCGA-60-2706-11A-01W-0877-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4448eef-1e9d-47c9-b2fe-9b5e42db2bf1

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASZ1 | c.945G>A p.K315= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52912777, COSV99498075; called by muse, mutect2, varscan2
- CD36 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV59218415; called by muse, mutect2
- HSD17B3 | c.297T>A p.S99R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV64558206; called by muse, mutect2, varscan2
- MMP16 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV54188081, COSV99688787; called by muse, mutect2, varscan2
- OGDHL | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65104199; called by muse, mutect2
- OR10G9 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs367825765, COSV100901696, COSV66686723; called by mutect2, varscan2
- OR4K5 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100262410, COSV60003280; called by muse, mutect2, varscan2
- PHF20L1 | c.2647G>C p.D883H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.28); catalogued as COSV99621410; called by muse, mutect2, varscan2
- SLC4A10 | c.1762C>A p.L588M (on ENST00000446997 / NM_001354461.2; = p.L558M on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55763123, COSV99764497; called by muse, mutect2, varscan2
- TG | c.7337C>A p.S2446Y | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55091024; called by muse, varscan2
- TMX1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63335460; called by muse, mutect2, varscan2
- MUSK | c.2138T>A p.M713K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TREM2 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- UNC13C | c.2402T>A p.L801Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR5F1 | c.348G>T p.G116= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
